Somatic mutation profile of tumor specimen HCM-CSHL-0462-D05-31B (aliquot HCM-CSHL-0462-D05-31B-01D-A83U-36) from HCMI case HCM-CSHL-0462-D05, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Intraductal carcinoma, noninfiltrating, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 49.1 years (17,939 days).
Specimen HCM-CSHL-0462-D05-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3ea48bd-8815-44af-9958-8f1b9b87c754.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0462-D05-10A (Blood Derived Normal), aliquot HCM-CSHL-0462-D05-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6d56a99-587b-4d53-baad-a50c15e0db04

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 378/1266 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KNDC1 | c.303C>T p.D101= | Splice Region (SNP) | VAF 59/244 reads (24%) | catalogued as rs770540856, COSV100464610; called by muse, mutect2, varscan2
- RARRES1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1335366665, COSV52961577; called by muse, mutect2, varscan2
- TSG101 | c.846C>T p.A282= | Splice Region (SNP) | VAF 148/510 reads (29%) | catalogued as rs369798357; called by muse, mutect2, varscan2
- ESRP1 | c.82_84del p.K28del | In Frame Del (DEL) | VAF 85/625 reads (14%) | called by mutect2, varscan2
- KCTD3 | c.766A>G p.S256G | Missense Mutation (SNP) | VAF 36/1484 reads (2%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by muse, mutect2
- MAP3K1 | c.4210G>A p.E1404K | Missense Mutation (SNP) | VAF 305/1046 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MBD6 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 102/330 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- OSBP2 | c.2124G>T p.K708N | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- ZGRF1 | c.5984C>T p.A1995V | Missense Mutation (SNP) | VAF 54/1297 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZUP1 | c.867G>C p.R289S | Missense Mutation (SNP) | VAF 24/958 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2
- ALPK3 | c.4917C>T p.G1639= | Silent (SNP) | VAF 50/483 reads (10%) | catalogued as rs1193979581; called by muse, mutect2, varscan2
- NR1H4 | c.1353G>C p.L451= (on ENST00000551379 / NM_001206993.2; = p.L437= on NM_005123.4) | Silent (SNP) | VAF 38/1314 reads (3%) | catalogued as COSV51852295; called by muse, mutect2
- NRG3 | c.1644C>A p.P548= (on ENST00000404547 / NM_001370084.1; = p.P327= on NM_001165973.1) | Silent (SNP) | VAF 206/717 reads (29%) | called by muse, mutect2, varscan2
- RELB | c.258G>A p.G86= | Silent (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- RIMBP2 | c.2583G>A p.P861= | Silent (SNP) | VAF 107/396 reads (27%) | catalogued as rs143479429, COSV55472669; called by muse, mutect2, varscan2
- TBC1D9 | c.1710A>G p.E570= | Silent (SNP) | VAF 214/732 reads (29%) | catalogued as rs1233274772; called by muse, mutect2, varscan2
